TARGET case TARGET-10-PAPHEK — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4aa72d8f-ee08-5ad8-bb24-30f4a63c34e7

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 8 years; Vital status: Dead; Days to death: 647 days (1.8 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 8.7 years (3,187 days); Year of diagnosis: 2006; Days to last follow up: 647 days (1.8 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (1 entry)
- Days to follow up: 647 days (1.8 years); Days to first event: 647 days (1.8 years); First event: Death; Year of follow up: 2007.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Positive.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 465 ×10³/µL.
- Day 8: Bone Marrow blast count 90%.
- Day 15: Bone Marrow blast count 15%.
- Day 29: Bone Marrow blast count 4%; Minimal Residual Disease (Flow Cytometry) 11%.

Biospecimens (5 samples)
- Samples TARGET-10-PAPHEK-03A, TARGET-10-PAPHEK-03B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PAPHEK-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPHEK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PAPHEK-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 647
- WBC at Diagnosis: 465
- CNS Status at Diagnosis: CNS 3
- MRD Day 29: 11
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Positive
- BMA Blasts Day 8: 90
- BMA Blasts Day 15: 15
- BMA Blasts Day 29: 4
- Karyotype: 46,XX,t(9;22)(q34;q11.2)[20]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: BCR-ABL1
